Somatic mutation profile of tumor specimen C3L-00780-03 (aliquot CPT0070330010) from CPTAC case C3L-00780, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.2 years (25,267 days).
Specimen C3L-00780-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8117f5c8-2790-4fa4-bc2b-f19bbad144a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00780-31 (Blood Derived Normal), aliquot CPT0071010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/483edc0a-caaa-417d-abf2-7fabc4953bc0

The open-access MAF lists 94 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Intron 7, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 3, 3'UTR 3, In Frame Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 128/299 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 224/621 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABR | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.37); catalogued as COSV100214825; called by muse, mutect2, varscan2
- ATP12A | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771242833; called by muse, mutect2, varscan2
- BRD1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164193595, COSV53456242; called by muse, mutect2, varscan2
- CFAP65 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs766938631, COSV58558638; called by muse, mutect2, varscan2
- CHD4 | c.2336G>A p.R779Q (on ENST00000357008 / NM_001363606.2; = p.R792Q on NM_001273.5) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58897494; called by muse, mutect2, varscan2
- CLK3 | c.1028G>A p.R343Q (on ENST00000395066 / NM_001130028.1; = p.R195Q on NM_003992.4) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1326540251, COSV100776026; called by muse, mutect2, varscan2
- CNTN1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs773587445, COSV61638896; called by muse, mutect2, varscan2
- CRELD1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.702); catalogued as rs1278960356, COSV55976461; called by muse, mutect2, varscan2
- DDX39A | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as rs1217352698, COSV54391613; called by muse, varscan2
- DOCK4 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs1382037895, COSV70235406; called by muse, mutect2, varscan2
- EXTL3 | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 115/504 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as rs546457214; called by muse, mutect2, varscan2
- EYS | c.7033C>T p.R2345C | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs756116965; called by muse, mutect2, varscan2
- GLYATL2 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as rs755639436; called by muse, mutect2, varscan2
- GRM2 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150657954; called by muse, mutect2, varscan2
- HOXA4 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs1404705406; called by muse, mutect2, varscan2
- IGBP1 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs781617904, COSV60556084; called by muse, mutect2, varscan2
- IGHM | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.2); catalogued as rs868948115; called by muse, mutect2
- KIAA0100 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as rs766496204; called by muse, mutect2, varscan2
- LHFPL3 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs767910543, COSV67813165; called by muse, mutect2, varscan2
- MCF2L | c.1760G>C p.R587P (on ENST00000375608; = p.R555P on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV65050572, COSV65051280; called by muse, mutect2, varscan2
- NPAS4 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs375164036; called by muse, mutect2, varscan2
- OR10H5 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs372973246, COSV100454604; called by muse, mutect2, varscan2
- PCDH19 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV99720239; called by muse, mutect2, varscan2
- PCDHB16 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 92/505 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53359476; called by muse, mutect2, varscan2
- PCDHGA8 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.258); catalogued as rs368785983, COSV99530075; called by muse, mutect2, varscan2
- PDE1C | c.2061C>A p.Y687* | Nonsense Mutation (SNP) | VAF 30/188 reads (16%) | catalogued as rs368406121; called by muse, mutect2, varscan2
- PDXK | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1162208844, COSV52361105; called by muse, mutect2
- PIGQ | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs752492969; called by muse, mutect2, varscan2
- PIK3R1 | c.1729dup p.R577Kfs*25 (on ENST00000521381 / NM_181523.3; = p.R307Kfs*25 on NM_181504.4) | Frame Shift Ins (INS) | VAF 35/146 reads (24%) | catalogued as COSV57136309; called by mutect2, pindel, varscan2
- PLEC | c.7982T>C p.V2661A (on ENST00000322810 / NM_201380.4; = p.V2551A on NM_000445.5) | Missense Mutation (SNP) | VAF 77/424 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.239); catalogued as rs1554689076, COSV59656333; called by muse, mutect2, varscan2
- PTEN | c.878del p.G293Efs*14 | Frame Shift Del (DEL) | VAF 67/369 reads (18%) | catalogued as COSV64306603; called by mutect2, pindel, varscan2
- RBM28 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760527493; called by muse, mutect2, varscan2
- TMEM129 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370130679, COSV100304904; called by muse, mutect2
- YTHDC1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as rs200384143; called by muse, mutect2, varscan2
- ZNF367 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as rs774097859; called by muse, mutect2, varscan2
- ACAD10 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- AFAP1L1 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2
- AGTPBP1 | c.1800_1802del p.E600del (on ENST00000357081 / NM_001330701.2; = p.E560del on NM_015239.2) | In Frame Del (DEL) | VAF 34/178 reads (19%) | called by mutect2, pindel, varscan2
- ASS1 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 133/578 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC150 | c.58C>G p.H20D | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CCDC88B | c.2584_2585dup p.E863Gfs*77 | Frame Shift Ins (INS) | VAF 38/181 reads (21%) | called by mutect2, pindel, varscan2
- CD93 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- CDHR1 | c.1733A>T p.K578M | Missense Mutation (SNP) | VAF 178/428 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CLRN2 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- EFCC1 | c.865C>G p.R289G | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- EGF | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.014); called by muse, mutect2
- EPB42 | c.73G>A p.A25T (on ENST00000441366 / NM_001114134.2; = p.A55T on NM_000119.3) | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FBLN1 | c.63_64del p.L22Afs*75 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by pindel, varscan2
- GIGYF2 | c.1963C>T p.Q655* | Nonsense Mutation (SNP) | VAF 92/366 reads (25%) | called by muse, varscan2
- KCNQ2 | c.2450T>A p.L817H (on ENST00000359125 / NM_172107.4; = p.L789H on NM_004518.6) | Missense Mutation (SNP) | VAF 118/526 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LAMA5 | c.5189A>C p.E1730A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MUC17 | c.862del p.V288Sfs*19 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- OTUD4 | c.2663_2665del p.G888del (on ENST00000447906 / NM_001366057.1; = p.G823del on NM_001102653.1) | In Frame Del (DEL) | VAF 34/144 reads (24%) | called by mutect2, pindel, varscan2
- PCDHB14 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 117/521 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PCF11 | c.2747G>C p.R916T | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PELP1 | c.2746G>T p.D916Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PPP1R10 | c.2026G>C p.G676R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- PRMT9 | c.846+1G>A p.X282_splice | Splice Site (SNP) | VAF 17/227 reads (7%) | called by muse, mutect2
- SCAF4 | c.2808_2811del p.D936Efs*147 | Frame Shift Del (DEL) | VAF 21/126 reads (17%) | called by mutect2, pindel, varscan2
- SH3RF1 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SOX17 | c.301_302dup p.M101Ifs*10 | Frame Shift Ins (INS) | VAF 30/179 reads (17%) | called by mutect2, pindel, varscan2
- SYN1 | c.721A>C p.T241P | Missense Mutation (SNP) | VAF 110/612 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.42344A>G p.Y14115C (on ENST00000591111; = p.Y6691C on NM_003319.4) | Missense Mutation (SNP) | VAF 27/127 reads (21%) | PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZDBF2 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- AC127029.3 | c.684C>T p.N228= | Silent (SNP) | VAF 115/480 reads (24%) | catalogued as rs41295041; called by muse, mutect2, varscan2
- BRINP1 | c.1797C>T p.N599= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- EPHX2 | c.384C>T p.D128= | Silent (SNP) | VAF 62/288 reads (22%) | catalogued as rs746553840, COSV100994482; called by muse, varscan2
- GPC6 | c.1512C>T p.D504= | Silent (SNP) | VAF 107/533 reads (20%) | catalogued as rs776151903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCY2D | c.3036C>T p.T1012= | Silent (SNP) | VAF 54/253 reads (21%) | catalogued as rs376759049; called by muse, mutect2, varscan2
- HCRTR1 | c.276C>T p.D92= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs200892324; called by muse, mutect2, varscan2
- HRNR | c.636C>T p.S212= | Silent (SNP) | VAF 51/264 reads (19%) | catalogued as rs201296154, COSV64257258; called by muse, mutect2, varscan2
- KBTBD6 | c.1866C>T p.C622= | Silent (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- PATE3 | c.141C>T p.G47= | Silent (SNP) | VAF 36/207 reads (17%) | catalogued as rs1055055393, COSV71323265; called by muse, mutect2, varscan2
- PRDM13 | c.2010C>T p.P670= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs1473325295; called by muse, mutect2, varscan2
- PTPRB | c.33C>T p.T11= | Silent (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- RABEPK | c.468G>A p.G156= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as rs1198101881; called by muse, mutect2, varscan2
- RBFOX1 | c.1056C>T p.Y352= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs372365163; called by muse, mutect2, varscan2
- SLC2A1 | c.954G>A p.T318= | Silent (SNP) | VAF 27/255 reads (11%) | catalogued as rs144831524; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC44A1 | c.1947G>A p.P649= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs560665933, COSV100570382; called by muse, mutect2, varscan2
- TMEM132E | c.309G>A p.V103= | Silent (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- ZNF646 | c.2952T>C p.T984= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659587 C>T | 5'Flank (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2
- F8 | c.6429+9882G>A | Intron (SNP) | VAF 77/327 reads (24%) | called by muse, mutect2, varscan2
- FAM50A | c.829+10G>A | Intron (SNP) | VAF 47/294 reads (16%) | catalogued as rs782192216; called by muse, mutect2, varscan2
- FHOD3 | c.*3C>T | 3'UTR (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- GABRE | c.1137+127G>A | Intron (SNP) | VAF 59/341 reads (17%) | catalogued as rs756770199; called by muse, mutect2, varscan2
- NDUFAF6 | c.298-1435C>T | Intron (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1172+65C>T | Intron (SNP) | VAF 31/148 reads (21%) | catalogued as rs1206084502; called by muse, mutect2, varscan2
- PRKCB | c.174-37C>A | Intron (SNP) | VAF 26/168 reads (15%) | catalogued as COSV57791078; called by muse, mutect2, varscan2
- SEC31B | c.1411-558G>A | Intron (SNP) | VAF 33/274 reads (12%) | catalogued as rs917624738; called by muse, mutect2, varscan2
- SIRT3 | c.*29G>T | 3'UTR (SNP) | VAF 19/81 reads (23%) | called by muse, varscan2
- TIMP3 | c.*3G>A | 3'UTR (SNP) | VAF 14/90 reads (16%) | catalogued as rs373056570; called by muse, mutect2, varscan2
